Somatic mutation profile of tumor specimen TARGET-30-PAVAYF-01A (aliquot TARGET-30-PAVAYF-01A-01D) from TARGET case TARGET-30-PAVAYF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 8.2 years (2,997 days).
Specimen TARGET-30-PAVAYF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c059fe37-a9b8-44c4-ada8-990a51c7577a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAVAYF-10A (Blood Derived Normal), aliquot TARGET-30-PAVAYF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31fdcf84-3632-4d36-8a86-bb14c259238c

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 95/98 reads (97%) | hotspot (GDC flag); catalogued as COSV64870748; called by muse, mutect2, varscan2
- RLIM | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60329721; called by muse, mutect2, varscan2
- SIGLEC1 | c.4904G>A p.R1635H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs377255910; called by mutect2, varscan2
- EZH2 | c.1708C>G p.Q570E (on ENST00000460911 / NM_001203247.2; = p.Q575E on NM_004456.5) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.347); called by muse, mutect2
- LPP | c.*2185C>A | 3'UTR (SNP) | VAF 56/122 reads (46%) | catalogued as rs1479499886, COSV57121015; called by muse, mutect2, varscan2
- PHF2 | c.*436del | 3'UTR (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
